Gene-level copy-number profile of tumor specimen TCGA-CN-A497-01A from TCGA case TCGA-CN-A497, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 63.8 years (23,310 days).
Specimen TCGA-CN-A497-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.d0573c02-4694-407d-8289-d6bd718a53da.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-A497-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/28db32fe-9f7f-4228-84da-3f9b7a18d1d3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,320; copy number 2: 42,856; copy number 3: 3,750; copy number 4: 767; copy number 5: 423; copy number 6: 99; copy number 7: 119; copy number 8: 8; copy number 9: 21; copy number 12: 14; copy number 14: 259; copy number 16: 117; copy number 23: 55.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-A497-01A-11D-A24C-01): tumor purity 0.67, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,081 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:564,296–25,250,936, 642 genes, copy number 5–23 (broad region; genes not listed).
- chr18:47,390–15,330,282, 376 genes, copy number 14–16 (broad region; genes not listed).
- chr18:23,957,754–27,247,188, 63 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,956. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
